CCDI case PBCFUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c77170c6-cd4c-4afa-ac0d-a458d3486311

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (740 days).

Biospecimens (3 samples)
- Sample 0DRVOI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRVOS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRVOY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
